Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AS, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AS-01A (Primary Tumor).

D.O.B.
MRN #
Ref Physi

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right and left pelvic lymph nodes; excision:
No metastatic carcinoma identified in five lymph nodes (0/5).

B. Prostate; radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 41 gram, 4.0 x 4.0 x 3.0 cm.
3. Tumor quantitation: Tumor occupies approximately 1-3% of the prostate gland volume, right side.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved: Surgical margins including base, apex, and inked prostate margins are negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes received: 5 pelvic node (see specimen A).
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/5).

Other:

1. Perineural invasion present.
2. pTNM stage: T2a N0.

CLF ICD-0-3
Adenocarcinoma, Gleason 8/10/13
path
Adenocarcinoma NOS 8/10/13
Site Prostate NOS 6/19
9/25/13

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate CA.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right and left pelvic lymph nodes.
- B. Prostate, right yellow, left black.

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers each labeled with the patient name

A. A is additionally designated #1 and consists of a 4 x 3.5 x 1.5 cm. aggregate of yellow lobular adipose tissue within which are five possible lymph nodes ranging from 0.4 to 3 cm. in greatest dimension. The lymph nodes are submitted entirely in cassettes A1-A6 as follows: A1 are three possible lymph nodes submitted in toto; A2 and 3 is one lymph node bisected and A4 through 6 is the largest lymph node trisected.

B. Part B is additionally designated #2 and consists of a 40.9 gram (following tissue procurement), 4 (left to right) x 4 (apex to base) x 3 (anterior to posterior) cm. prostate with attached bilateral seminal vesicals and vas deferens. The right seminal vesical is 5.1 x 2 x 1.2 cm. and the right vas deferens is 4 cm. in length by 0.5 cm. in diameter. The left seminal vesical is 5.2 x 2 x 1.1 cm. and the left vas deferens is 2.5 cm. in length by 0.5 cm. in diameter. On the requisition it states that the prostate is inked as follows: right is yellow and left is black, however, the prostate is actually inked right

black, left yellow. The prostate has been previously sectioned for tissue procurement. The specimen is further sectioned from apex to base to reveal a central zone that is pink-tan and smooth. The peripheral zone is pink-tan and smooth. In the base of the prostate is a 1 x 1 x 0.6 cm. white-tan area of induration that is abutting the right posterior aspect. The seminal vesicals are free of tumor and representative sections are submitted in cassettes B1-B15 as follows: B1 and B2 is the apical margin coned and then radially sectioned; B3 is the base margin coned and then radially sectioned; B4 and 5 is the apex of the prostate bisected; B6 and B7 is the mid prostate bisected; B8 through 11 is the base of the prostate to include the possible lesion submitted right anterior, right posterior, left anterior, left posterior; B12 is additional right posterior base to include possible mass; B13 is the seminal vesicals at the point of attachment bisected; B14 is right seminal vesical and B15 is left seminal vesical. Additionally there are three research cassettes labeled All cassettes are labeled

Reviewed Initials	KMI	9/30/13

Source: NCI Genomic Data Commons file a5b25a4d-8258-4529-af8c-618d49f28832 (TCGA-HC-A6AS.89891821-AF8C-4105-8270-D6FCF714697F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).